Gene-level copy-number profile of tumor specimen TCGA-CV-7235-01A from TCGA case TCGA-CV-7235, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 67.9 years (24,800 days).
Specimen TCGA-CV-7235-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.cba63cf4-701c-4af8-b7dc-9df044483835.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7235-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9254399b-19eb-40d4-b599-c21be5152671

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 909; copy number 2: 21,345; copy number 3: 21,738; copy number 4: 11,966; copy number 5: 906; copy number 6: 1,706; copy number 7: 499; copy number 8: 170; copy number 9: 65; copy number 10: 146; copy number 11: 23; copy number 12: 86; copy number 15: 59; copy number 23: 6; copy number 25: 4; copy number 31: 61; copy number 37: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7235-01A-11D-2010-01): tumor purity 0.54, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–31,381,490, 129 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,120 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,129,464–44,390,823, 208 genes, copy number 10–12 (broad region; genes not listed).
- chr2:167,631,480–176,339,077, 161 genes, copy number 8 (broad region; genes not listed).
- chr2:176,506,245–176,531,683, 2 genes, copy number 8: AC017048.1, AC017048.2.
- chr2:177,623,244–178,108,339, 2 genes, copy number 9 (within-gene range 5–9): PDE11A, PDE11A.
- chr2:177,953,111–193,277,614, 191 genes, copy number 7–9 (broad region; genes not listed).
- chr4:37,891,084–39,182,258, 24 genes, copy number 7–9 (within-gene range 2–9): TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2.
- chr5:58,198–3,181,487, 87 genes, copy number 7 (broad region; genes not listed).
- chr5:15,500,180–15,939,795, 1 gene, copy number 7 (within-gene range 4–7): FBXL7.
- chr5:15,935,182–21,779,522, 90 genes, copy number 7 (broad region; genes not listed).
- chr5:21,882,585–22,213,761, 4 genes, copy number 7: HSPD1P1, AC139497.1, PMCHL1, AC138854.1.
- chr5:39,520,398–39,572,639, 2 genes, copy number 10: LINC02104, CCDC11P1.
- chr9:31,505,280–31,645,160, 3 genes, copy number 8: MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:33,695,767–36,171,334, 134 genes, copy number 7 (broad region; genes not listed).
- chr11:68,707,440–70,436,584, 53 genes, copy number 15 (within-gene range 3–15): TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 15: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:98,130,239–98,945,079, 4 genes, copy number 25–37: AP001317.1, AP003038.1, AP003715.1, AP002428.1.
- chr11:99,120,176–104,252,651, 68 genes, copy number 23–31 (broad region; genes not listed).
- chr11:104,873,264–105,531,697, 16 genes, copy number 9 (within-gene range 2–9): AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP.
- chr11:123,902,167–124,055,707, 11 genes, copy number 11: OR8D4, OR4D5, OR6T1, OR10S1, OR10G6, OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P.
- chr18:721,588–927,993, 12 genes, copy number 11 (within-gene range 5–11): YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904.
- chr18:6,727,053–7,461,135, 15 genes, copy number 9: AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, AP001095.1.
- chr18:36,108,531–37,992,413, 22 genes, copy number 10 (within-gene range 2–10): SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1.
- chr18:41,341,319–41,819,421, 4 genes, copy number 8: AC079052.1, KC6, NPM1P1, AC011225.1.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
